Somatic mutation profile of tumor specimen TCGA-DD-A3A0-01A (aliquot TCGA-DD-A3A0-01A-11D-A20W-10) from TCGA case TCGA-DD-A3A0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.9 years (25,889 days).
Specimen TCGA-DD-A3A0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54358be5-0dd2-46b9-ba01-2e1c7c4b2e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A0-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A0-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7ad6efa-36c4-43f7-bb2e-a5ef297c8e8a

The open-access MAF lists 337 somatic variants for this specimen: 315 protein-altering or splice-affecting, 10 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 275, Missense Mutation 33, Silent 10, Intron 6, Splice Site 5, RNA 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX4 | c.398del p.P133Rfs*48 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs1085307637, COSV61327307; ClinVar: likely pathogenic; called by mutect2, pindel
- NPHP3 | c.406del p.T136Rfs*13 | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | catalogued as rs1379989124, CD1211305; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- PAFAH1B1 | c.152del p.L51Wfs*18 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as rs587784253; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.750T>A p.C250* | Nonsense Mutation (SNP) | VAF 44/64 reads (69%) | catalogued as rs767623493, CD1513179, COSV64299167; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 70/114 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- ACTR5 | c.1796del p.G599Vfs*63 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as COSV99710039; called by mutect2, pindel
- ADAMTS9 | c.4799G>A p.R1600Q | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs140575639; called by mutect2, varscan2
- AHNAK2 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs137934113; called by mutect2, varscan2
- APBB1IP | c.471del p.A158Pfs*13 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as COSV63302193; called by mutect2, pindel
- BAHD1 | c.300del p.S101Afs*107 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as COSV69084900; called by mutect2, pindel
- BCORL1 | c.5003del p.P1668Lfs*33 | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | catalogued as COSV99501023; called by mutect2, pindel
- BRD1 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV53458607; called by mutect2, varscan2
- C2orf42 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV52451133; called by muse, varscan2
- CACNA1A | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs781738239, COSV64202292; called by mutect2, varscan2
- CASD1 | c.1006A>G p.N336D | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.331); catalogued as rs1293217844, COSV51973500; called by mutect2, varscan2
- CDC42BPG | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1287189172, COSV61346874; called by mutect2, varscan2
- CIPC | c.786del p.A263Pfs*14 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs1566806658, COSV62377091; called by mutect2, pindel
- COL8A1 | c.856del p.L286Wfs*95 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as COSV53729681; called by mutect2, pindel
- CPN2 | c.439del p.L147Wfs*22 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | catalogued as COSV60470937; called by mutect2, pindel
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by mutect2, varscan2
- DKC1 | c.1142del p.G381Vfs*2 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as COSV101059869; called by mutect2, pindel
- DYRK4 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV50540946; called by mutect2, varscan2
- ENPEP | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs373049379, COSV54447019; called by mutect2, varscan2
- ERICH3 | c.1002del p.T335Pfs*20 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV58617304; called by mutect2, pindel
- F8 | c.4085del p.N1362Tfs*2 | Frame Shift Del (DEL) | VAF 9/101 reads (9%) | catalogued as COSV100812178; called by mutect2, pindel
- F8 | c.3668del p.L1223* | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as CD145604, CM103777; called by mutect2, pindel
- F8 | c.2777del p.P926Qfs*11 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | catalogued as CD055662, CD0911171; called by mutect2, pindel
- FOXK1 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV61066894; called by muse, varscan2
- HCN4 | c.2618del p.P873Hfs*27 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as COSV56085419; called by mutect2, pindel
- HHLA2 | c.669del p.R224Afs*4 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | catalogued as COSV63317036; called by mutect2, pindel
- IFNA2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.637); catalogued as COSV66505705; called by mutect2, varscan2
- ITPKB | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs149543375; called by mutect2, varscan2
- JMJD1C | c.4380del p.S1460Rfs*23 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | catalogued as COSV104403648; called by mutect2, pindel
- KCNB2 | c.33del p.K12Rfs*71 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | catalogued as COSV73048927, COSV73051668; called by mutect2, pindel
- KCNJ12 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782569468, COSV59174352; called by mutect2, varscan2
- KCNK18 | c.250del p.Q84Rfs*7 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV100572127; called by mutect2, pindel
- KDM2B | c.3152del p.P1051Rfs*57 | Frame Shift Del (DEL) | VAF 20/191 reads (10%) | catalogued as COSV65643838; called by mutect2, pindel
- LAMB2 | c.2167del p.R723Vfs*5 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV100565530; called by mutect2, pindel
- LANCL3 | c.1073del p.G358Efs*45 (on ENST00000378619 / NM_001170331.2; = p.G358Efs*15 on NM_198511.3) | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV66127806; called by mutect2, pindel
- LCT | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.253); catalogued as COSV51467462; called by muse, mutect2, varscan2
- MAPK14 | c.748del p.I250Sfs*13 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | catalogued as rs150174370; called by mutect2, pindel
- MFSD6L | c.308del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as COSV61006209; called by mutect2, pindel
- MFSD9 | c.1326dup p.S443Qfs*22 | Frame Shift Ins (INS) | VAF 28/119 reads (24%) | catalogued as rs769987847; called by mutect2, varscan2
- MROH6 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs368816807; called by muse, varscan2
- MUC16 | c.2344C>G p.P782A | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV67476217; called by mutect2, varscan2
- MX1 | c.1962del p.R655Afs*39 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as COSV55818543; called by mutect2, pindel
- MYH1 | c.3397del p.R1133Gfs*35 | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | catalogued as COSV56844141; called by mutect2, pindel
- NAA25 | c.2425C>G p.L809V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55705640; called by muse, varscan2
- NECTIN2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52978225; called by mutect2, varscan2
- NLRP14 | c.3266G>T p.W1089L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55068826; called by mutect2, varscan2
- NPHS1 | c.3442del p.Q1148Sfs*32 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as CM011443; called by mutect2, pindel
- NRG3 | c.649del p.S217Vfs*90 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as COSV64553648; called by mutect2, pindel
- OR10J5 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58386654; called by mutect2, varscan2
- OR9G4 | c.206del p.L69Wfs*39 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | catalogued as rs781668122; called by mutect2, pindel
- OSBPL3 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV57658410; called by muse, varscan2
- OTC | c.996del p.W332* | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as CM062998, CM155243; called by mutect2, pindel
- PLCL1 | c.2525T>A p.F842Y | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70842405; called by mutect2, varscan2
- PLXNA4 | c.1237del p.L413Wfs*20 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | catalogued as COSV100322501; called by mutect2, pindel
- PLXNA4 | c.27del p.C10Afs*69 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | catalogued as COSV100324572; called by mutect2, pindel
- PRRC2A | c.5649del p.G1884Afs*12 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | catalogued as COSV52991311; called by mutect2, pindel
- PTPRC | c.1054A>G p.K352E | Missense Mutation (SNP) | VAF 112/166 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61406412; called by mutect2, varscan2
- RAB11FIP5 | c.891del p.K298Sfs*109 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV99241854; called by mutect2, pindel
- RANGAP1 | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV62363949; called by muse, mutect2, varscan2
- RCOR2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56850516; called by mutect2, varscan2
- RERE | c.2792del p.P931Rfs*29 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as COSV61944158; called by mutect2, pindel
- RPS6KB2 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.867); catalogued as rs1034596803, COSV57048458; called by muse, varscan2
- SH2D4A | c.1049del p.X350_splice | Splice Site (DEL) | VAF 3/25 reads (12%) | catalogued as COSV56125566; called by mutect2, pindel
- SLC35D3 | c.337del p.L113Wfs*39 | Frame Shift Del (DEL) | VAF 18/212 reads (8%) | catalogued as COSV59377909; called by mutect2, pindel
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs745516519; called by mutect2, varscan2
- TLCD3A | c.764del p.K255Rfs*31 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs1238973966; called by mutect2, pindel
- TLL2 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63573558; called by muse, varscan2
- TPP2 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.223); catalogued as COSV65753406; called by mutect2, varscan2
- TTC25 | c.801del p.S268Hfs*34 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | catalogued as COSV101103012; called by mutect2, pindel
- USP17L2 | c.1239del p.C414Afs*21 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV100414742, COSV61555451; called by mutect2, pindel
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs749830910; called by mutect2, varscan2
- USPL1 | c.2326del p.S776Qfs*8 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV54998516; called by mutect2, pindel
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by pindel, varscan2
- XDH | c.780del p.N261Tfs*8 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as COSV65150946; called by mutect2, pindel
- ZFP14 | c.762del p.K254Nfs*126 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as COSV54202558; called by mutect2, pindel
- AADAC | c.913del p.S305Lfs*11 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- ABAT | c.1364del p.L455* | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- ABCC3 | c.794del p.K265Sfs*36 | Frame Shift Del (DEL) | VAF 6/84 reads (7%) | called by mutect2, pindel
- AC011448.1 | c.396del p.L133Wfs*30 | Frame Shift Del (DEL) | VAF 13/141 reads (9%) | called by mutect2, pindel
- AC090517.4 | c.1863del p.D622Ifs*26 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- ADAMTSL2 | c.915del p.T306Pfs*5 | Frame Shift Del (DEL) | VAF 5/64 reads (8%) | called by mutect2, pindel
- ADGRF2 | c.1244del p.N415Tfs*27 (on ENST00000296862 / NM_001368115.2; = p.N347Tfs*27 on NM_153839.7) | Frame Shift Del (DEL) | VAF 5/64 reads (8%) | called by mutect2, pindel
- AHR | c.2378del p.P793Qfs*7 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ALKBH4 | c.673del p.V225Cfs*87 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ANKRD30A | c.4133del p.N1378Tfs*3 (on ENST00000611781; = p.N1322Tfs*3 on NM_052997.2) | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- AP5S1 | c.211del p.A71Hfs*50 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- APC | c.5058del p.K1686Nfs*23 | Frame Shift Del (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel
- ARHGEF40 | c.668del p.G223Vfs*24 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ARHGEF6 | c.950del p.G317Efs*5 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- ATF7IP | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- ATRNL1 | c.1397del p.G466Vfs*12 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- AURKA | c.359del p.N120Mfs*63 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- B3GNT8 | c.295del p.A99Pfs*69 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- BLK | c.6del p.L3_?2 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- BLVRA | c.806del p.K269Rfs*33 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- BNC2 | c.3026del p.P1009Lfs*7 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- BRAT1 | c.477del p.F159Lfs*60 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- BRD1 | c.2338G>T p.G780W | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by mutect2, varscan2
- C18orf54 | c.671del p.K224Rfs*8 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- C4B | c.4068G>T p.E1356D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by mutect2, varscan2
- C7orf57 | c.228del p.G77Vfs*7 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- CACNG4 | c.791del p.K264Rfs*23 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- CADPS2 | c.859del p.M287Wfs*11 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- CAMK4 | c.816del p.N272Kfs*9 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- CARMIL2 | c.3683del p.G1228Vfs*69 | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- CASK | c.1769del p.P590Qfs*28 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- CASKIN1 | c.1223del p.G408Afs*70 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- CASKIN2 | c.2358del p.T787Lfs*15 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- CCAR2 | c.388del p.L130Cfs*3 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CCDC88C | c.2395del p.L799Cfs*88 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CCDC92 | c.988del p.T330Lfs*16 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CDH20 | c.2109del p.E704Rfs*15 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CEP57L1 | c.648del p.A217Lfs*14 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- CHD2 | c.2011del p.W671Gfs*23 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CHD8 | c.2688del p.R896Sfs*3 (on ENST00000646647 / NM_001170629.2; = p.R617Sfs*3 on NM_020920.4) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CHST12 | c.207del p.L70Wfs*9 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CLDN2 | c.94del p.T32Qfs*10 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- CLVS1 | c.767del p.N256Tfs*6 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- CNOT2 | c.171+1del p.X57_splice | Splice Site (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- CNTNAP2 | c.2786del p.G929Afs*12 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- COA5 | c.125del p.L42* | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- COL18A1 | c.2864del p.P955Qfs*184 (on ENST00000359759 / NM_130444.3; = p.P720Qfs*184 on NM_030582.4) | Frame Shift Del (DEL) | VAF 9/105 reads (9%) | called by mutect2, pindel
- COL7A1 | c.8079del p.K2694Rfs*92 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- CPEB3 | c.854del p.P285Rfs*16 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CPT1B | c.2120del p.G707Afs*9 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- CPZ | c.1559del p.N520Tfs*52 (on ENST00000360986 / NM_001014447.3; = p.N509Tfs*52 on NM_003652.3) | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- CRPPA | c.884del p.N295Tfs*4 (on ENST00000407010 / NM_001368197.1; = p.N245Tfs*4 on NM_001101417.4) | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- CRYBG1 | c.5716del p.X1906_splice | Splice Site (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- CSPG4 | c.6487del p.E2163Sfs*53 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- CYSLTR2 | c.679del p.V227Ffs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CYTH1 | c.960del p.K320Nfs*120 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- DCHS1 | c.9394del p.D3132Tfs*16 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- DCT | c.79del p.R27Efs*4 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel
- DMD | c.2674del p.I892Ffs*4 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- DNAH7 | c.3360_3361del p.S1120Rfs*26 | Frame Shift Del (DEL) | VAF 54/217 reads (25%) | called by mutect2, pindel, varscan2
- DNAH8 | c.1852del p.M618* | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- DOCK5 | c.4713del p.F1571Lfs*19 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by pindel, varscan2
- DTX3L | c.240del p.K80Nfs*14 | Frame Shift Del (DEL) | VAF 13/152 reads (9%) | called by mutect2, pindel
- DYNC1LI1 | c.1364del p.K455Rfs*10 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | called by mutect2, pindel
- EIF4G3 | c.3227del p.G1076Efs*23 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | called by mutect2, pindel
- EPPK1 | c.1201del p.T401Qfs*91 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ERP44 | c.890del p.L297Yfs*24 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- ESPNL | c.1970del p.G657Afs*28 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by pindel, varscan2
- ETV6 | c.940del p.Y314Tfs*2 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ETV7 | c.11del p.G4Efs*8 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- FAM76B | c.738del p.F246Lfs*4 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- FAT2 | c.5451del p.S1818Afs*5 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- FAT4 | c.12700del p.S4234Afs*12 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by mutect2, pindel
- FER1L6 | c.1949del p.K650Sfs*5 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by pindel, varscan2
- FGD6 | c.3270del p.L1091Sfs*6 | Frame Shift Del (DEL) | VAF 13/125 reads (10%) | called by mutect2, pindel
- FKBP10 | c.1373del p.P458Rfs*73 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | called by mutect2, pindel
- GABBR1 | c.528del p.M178* | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- GABRQ | c.1105del p.R369Efs*14 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- GALNT1 | c.1503del p.G502Afs*10 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- GALNT16 | c.1278del p.V427* | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- GGNBP2 | c.2036del p.L679* | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- GJB6 | c.425del p.F142Sfs*26 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- GNL1 | c.1631del p.G544Afs*17 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- GPRASP2 | c.214del p.A72Qfs*9 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- GPRIN1 | c.2190del p.A731Pfs*96 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- GUCY1B1 | c.1504del p.D502Tfs*2 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- HEATR5A | c.2380del p.V794Lfs*22 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by pindel, varscan2
- HPS6 | c.766del p.R256Efs*34 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- HS2ST1 | c.468del p.K156Nfs*8 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- HSD3B7 | c.1043del p.F348Sfs*69 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- HTR3E | c.293del p.P98Hfs*16 (on ENST00000415389 / NM_001256613.1; = p.P113Hfs*16 on NM_182589.2) | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- IER2 | c.133del p.E45Sfs*83 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- IFIT1 | c.228del p.E77Kfs*5 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 12/124 reads (10%) | called by pindel, varscan2
- IQSEC2 | c.1998del p.N667Tfs*55 (on ENST00000642864 / NM_001111125.3; = p.N462Tfs*55 on NM_015075.2) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- KIAA1109 | c.12304del p.A4102Lfs*21 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- KIAA1109 | c.14603del p.L4868* | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- KIAA1841 | c.718del p.M240Wfs*4 | Frame Shift Del (DEL) | VAF 14/170 reads (8%) | called by mutect2, pindel
- KIF3A | c.1881del p.N627Kfs*3 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- KLHDC2 | c.241del p.I81Sfs*19 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by pindel, varscan2
- KLHL24 | c.362del p.L121Cfs*9 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by pindel, varscan2
- KLHL26 | c.986del p.K329Rfs*21 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- KPNA3 | c.1005del p.L335Ffs*8 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- LAMTOR5 | c.177del p.T60Lfs*8 (on ENST00000602318 / NM_001382293.1; = p.T142Lfs*8 on NM_006402.3) | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- LARP1 | c.377del p.P126Rfs*11 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- LCMT2 | c.269del p.A90Vfs*10 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- LDB3 | c.1370del p.P457Qfs*35 | Frame Shift Del (DEL) | VAF 6/74 reads (8%) | called by mutect2, pindel
- LHX3 | c.796del p.M266Wfs*93 (on ENST00000371748 / NM_178138.6; = p.M271Wfs*93 on NM_014564.5) | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- LIMD1 | c.311del p.K104Sfs*99 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- LRBA | c.6031del p.T2011Qfs*11 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | called by mutect2, pindel
- LRGUK | c.938del p.K313Rfs*5 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- LRP1B | c.13699del p.M4567Wfs*10 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- LTN1 | c.1848del p.L617Ffs*33 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- MAP1S | c.669del p.F224Sfs*67 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- MAP3K15 | c.3563del p.N1188Tfs*7 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- MCMDC2 | c.1040del p.L347* | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- MED14 | c.2885del p.F962Sfs*2 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- MEGF8 | c.5102del p.P1701Hfs*29 (on ENST00000251268 / NM_001271938.2; = p.P1634Hfs*29 on NM_001410.3) | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- METTL8 | c.192del p.V65* | Frame Shift Del (DEL) | VAF 15/146 reads (10%) | called by mutect2, pindel
- MFHAS1 | c.1830del p.Q611Nfs*71 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- MFHAS1 | c.1267del p.T423Lfs*32 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- MISP | c.1090del p.D364Tfs*51 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- MOCOS | c.2163del p.D722Ifs*13 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- MRM2 | c.567del p.T190Hfs*19 | Frame Shift Del (DEL) | VAF 17/168 reads (10%) | called by mutect2, pindel, varscan2
- MRPS22 | c.151del p.R51Afs*31 (on ENST00000310776 / NM_001363893.1; = p.R51Afs*32 on NM_020191.4) | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- MTMR9 | c.1621del p.T541Qfs*43 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- MTOR | c.2681del p.L894Wfs*8 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- MYO18A | c.2550del p.T851Rfs*88 | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | called by mutect2, pindel
- N4BP1 | c.552del p.E185Nfs*3 | Frame Shift Del (DEL) | VAF 11/129 reads (9%) | called by mutect2, pindel
- N4BP2 | c.2020del p.S674Vfs*3 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- NCKAP1 | c.40del p.A14Rfs*44 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- NCOR1 | c.1914del p.G639Vfs*2 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by pindel, varscan2
- NCOR2 | c.2607del p.A870Pfs*94 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- NEXMIF | c.3202del p.L1068Ffs*22 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- NUMA1 | c.2058del p.A687Qfs*25 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- OBI1 | c.1808del p.N603Mfs*20 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- OBI1 | c.1317del p.N439Kfs*9 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- OR2T8 | c.484del p.L162* | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- OSBPL8 | c.2607del p.D870Tfs*8 | Frame Shift Del (DEL) | VAF 12/145 reads (8%) | called by mutect2, pindel
- PAFAH1B1 | c.65del p.N22Mfs*16 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PAGE1 | c.342del p.C115Vfs*20 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- PALLD | c.1477del p.K493Nfs*14 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PANK4 | c.1862del p.F621Sfs*7 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- PCDH10 | c.3020del p.K1007Rfs*16 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- PCDH17 | c.91del p.A31Pfs*4 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- PCDH7 | c.2260A>G p.T754A | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- PCDH9 | c.19del p.Y7Tfs*6 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- PCNT | c.8902del p.L2968Sfs*11 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- PDCD1LG2 | c.322del p.V108Sfs*8 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- PDS5B | c.2170del p.R724Vfs*32 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- PHLDB3 | c.216del p.E73Rfs*6 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- PIK3IP1 | c.292del p.D98Tfs*52 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- PIK3R1 | c.634+5_634+8del p.X212_splice | Splice Site (DEL) | VAF 32/133 reads (24%) | called by pindel, varscan2
- PKD1L1 | c.6893del p.L2298Cfs*3 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | called by mutect2, pindel
- PMS2 | c.1515del p.F506Sfs*89 | Frame Shift Del (DEL) | VAF 7/87 reads (8%) | called by mutect2, pindel
- POLQ | c.3067del p.T1023Qfs*6 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- POLR3A | c.319-2del p.X107_splice | Splice Site (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PPP4R3B | c.1118del p.G373Afs*18 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- PRAME | c.1487del p.Y496Lfs*30 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PRDM15 | c.507del p.V170Cfs*14 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PRICKLE4 | c.649del p.E217Kfs*22 (on ENST00000359201; = p.E257Kfs*22 on NM_013397.6) | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PRKD2 | c.1573del p.H525Tfs*6 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- PRKDC | c.1007del p.N336Ifs*41 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- PRLHR | c.996del p.F333Sfs*25 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- PSD | c.70del p.R24Afs*40 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- PTK7 | c.1038del p.K347Rfs*69 | Frame Shift Del (DEL) | VAF 15/158 reads (9%) | called by mutect2, pindel
- RAPGEF2 | c.3044del p.K1015Sfs*10 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- RBAK | c.688del p.E230Rfs*29 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- REPS2 | c.1913del p.K638Rfs*52 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- RIF1 | c.3817del p.S1273Qfs*8 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- ROCK2 | c.1601del p.N534Tfs*3 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- RPGR | c.2848del p.T950Qfs*13 (on ENST00000339363 / NM_001367249.1; = p.T745Qfs*13 on NM_000328.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by pindel, varscan2
- SAMD4A | c.1565del p.L522Yfs*4 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- SCNN1D | c.1787del p.G596Afs*17 (on ENST00000338555; = p.G760Afs*17 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- SEC24C | c.1509del p.F504Lfs*4 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- SEMA4B | c.2333del p.P778Lfs*63 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- SEPTIN4 | c.1568del p.S523Lfs*12 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- SHOC2 | c.876del p.R292Sfs*12 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SLC34A3 | c.1556del p.G519Vfs*48 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel
- SLC35E4 | c.525del p.C176Afs*43 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SLC38A10 | c.574del p.E192Rfs*32 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- SLC4A4 | c.2136del p.K712Nfs*15 (on ENST00000264485 / NM_001098484.3; = p.K668Nfs*15 on NM_003759.4) | Frame Shift Del (DEL) | VAF 11/126 reads (9%) | called by mutect2, pindel
- SLITRK1 | c.2036del p.N679Tfs*59 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SMARCA5 | c.1095del p.F365Lfs*16 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SNTB2 | c.1394del p.N465Mfs*24 | Frame Shift Del (DEL) | VAF 12/144 reads (8%) | called by mutect2, pindel
- SPAG6 | c.1374del p.V459Ffs*4 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by pindel, varscan2
- SPATA13 | c.1404del p.G469Afs*56 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- SPO11 | c.621del p.Q208Kfs*6 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- STING1 | c.653del p.N218Tfs*129 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | called by pindel, varscan2
- STT3B | c.742del p.W248Gfs*35 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- SUCLG1 | c.1031del p.K344Rfs*31 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TAF2 | c.551del p.N184Ifs*21 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TDRD3 | c.707del p.Q236Rfs*9 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- TEDC2 | c.220del p.L74Sfs*7 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- TEX14 | c.3960del p.A1321Pfs*24 (on ENST00000240361 / NM_001201457.2; = p.A1275Pfs*24 on NM_031272.5) | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- TEX44 | c.734del p.P245Rfs*32 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- TGDS | c.1010del p.N337Tfs*9 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TGIF2 | c.333del p.S112Qfs*47 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- TIMP3 | c.94del p.Q32Rfs*10 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- TLL1 | c.2183del p.F728Sfs*87 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TMEM208 | c.23del p.G8Afs*16 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel
- TNFRSF11A | c.1259del p.N420Tfs*106 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- TPO | c.2646del p.I884Sfs*11 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- TRIM65 | c.712del p.L238Wfs*25 | Frame Shift Del (DEL) | VAF 3/41 reads (7%) | called by mutect2, pindel
- TRIOBP | c.4373del p.G1458Afs*49 | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- TRIP12 | c.1132del p.Q378Kfs*9 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- TTC21B | c.3819del p.F1274Lfs*4 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- TTN | c.57677del p.P19226Lfs*2 (on ENST00000591111; = p.P11802Lfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TXNDC2 | c.*1del | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- TXNL1 | c.586del p.I196Ffs*25 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- UBAC1 | c.281del p.K94Sfs*52 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- UBN1 | c.1833del p.V612Sfs*21 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- USP38 | c.1461del p.K487Nfs*57 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- USPL1 | c.451del p.S151Qfs*88 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- UTP20 | c.8186del p.K2729Rfs*8 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- VASN | c.1877del p.G626Efs*2 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- VPS26C | c.434del p.P145Lfs*49 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- WFDC1 | c.313del p.L105* | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- WNT8B | c.181del p.D61Tfs*40 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by pindel, varscan2
- WRAP53 | c.599del p.P200Qfs*35 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- XPO4 | c.1681del p.I561Yfs*5 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- ZFYVE16 | c.3593del p.G1198Vfs*11 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | called by mutect2, pindel
- ZGLP1 | c.212del p.P71Lfs*61 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- ZMIZ1 | c.2655del p.Y886Tfs*26 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ZNF16 | c.144del p.C49Afs*100 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | called by mutect2, pindel
- ZNF17 | c.1135del p.V379Ffs*79 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- ZNF354B | c.1672del p.T558Lfs*49 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | called by mutect2, pindel, varscan2
- ZNF430 | c.372del p.D125Ifs*8 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- ZNF451 | c.683del p.R228Kfs*77 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF470 | c.1523del p.P508Lfs*101 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- ZNF675 | c.621del p.A208Lfs*69 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- ZNF687 | c.3697del p.A1233Lfs*36 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ZNF770 | c.1761del p.F587Lfs*59 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ZNF8 | c.1636del p.I546Sfs*43 | Frame Shift Del (DEL) | VAF 10/119 reads (8%) | called by mutect2, pindel
- ZNF85 | c.28del p.A10Pfs*2 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- ABCC10 | c.3135C>A p.I1045= (on ENST00000372530 / NM_001198934.2; = p.I1017= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/217 reads (36%) | catalogued as COSV55089823; called by mutect2, varscan2
- ADAM11 | c.1737G>C p.G579= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV52347433; called by muse, varscan2
- AIFM3 | c.351G>T p.V117= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV59000842; called by muse, mutect2, varscan2
- GCSAM | c.333C>T p.P111= | Silent (SNP) | VAF 76/236 reads (32%) | catalogued as COSV58263779; called by mutect2, varscan2
- PPP2R3A | c.663T>C p.D221= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1311575346, COSV53866483, COSV99388225; called by mutect2, varscan2
- PRDM1 | c.984C>T p.P328= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs542551556, COSV64845715; called by muse, mutect2, varscan2
- RHO | c.546C>T p.G182= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV56213940; called by mutect2, varscan2
- SUSD4 | c.909C>A p.I303= | Silent (SNP) | VAF 58/209 reads (28%) | catalogued as COSV59554176; called by mutect2, varscan2
- WNT5B | c.132C>G p.A44= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV60198315; called by mutect2, varscan2
- ZNF280B | c.780A>T p.A260= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV64529165; called by muse, mutect2, varscan2
- ACSM3 | c.639-62del | Intron (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- MAP3K4 | c.344-326del | Intron (DEL) | VAF 6/62 reads (10%) | catalogued as rs746497770; called by mutect2, pindel
- MSL3 | c.1171+84del | Intron (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- PDZD2 | c.8219-151del | Intron (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- PITPNM1 | c.-1del | 5'UTR (DEL) | VAF 4/36 reads (11%) | catalogued as COSV100039466; called by mutect2, pindel
- PRR12 | c.52-73del | Intron (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RCC1 | c.73+592del | Intron (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- SCARA3 | chr8:27676589 del A | 3'Flank (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SLC22A17 | n.1902del | RNA (DEL) | VAF 4/42 reads (10%) | catalogued as rs1316469477; called by pindel, varscan2
- TLR7 | c.*3del | 3'UTR (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- TLX1NB | n.1379del | RNA (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- YPEL3 | c.-11del | 5'UTR (DEL) | VAF 4/42 reads (10%) | catalogued as COSV54221052; called by mutect2, pindel
